Gene-level copy-number profile of tumor specimen ALCH-B29Q-TTP1-A from ALCHEMIST case ALCH-B29Q, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.3 years (23,843 days).
Specimen ALCH-B29Q-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 76eea54d-0a01-4554-b4be-8ab689462534.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B29Q-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/8db1dd66-1863-41dc-9315-a91d62d6ce21

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 701; copy number 2: 57,454; copy number 3: 204; copy number 4: 3; copy number 6: 3.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:220,786,990–220,884,503, 1 gene (within-gene range 0–2): AL445423.3.
- chr1:220,832,763–220,885,059, 2 genes: HLX-AS1, HLX.
- chr7:43,940,895–44,042,306, 10 genes (within-gene range 0–2): POLR2J4, AC004951.4, AC004951.3, AC004951.2, SPDYE1, AC004951.1, AC017116.2, POLR2J4, RASA4CP, LINC00957.
- chr10:72,332,830–72,355,149, 1 gene: DNAJB12.
- chr16:70,661,204–70,801,160, 9 genes (within-gene range 0–2): MTSS2, AC020763.4, VAC14, AC020763.3, AC020763.1, VAC14-AS1, AC020763.5, AC020763.2, AC027281.1.
- chr22:41,229,510–41,360,147, 4 genes (within-gene range 0–2): CHADL, RANGAP1, MIR6889, ZC3H7B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:15,282,557–15,304,556, 3 genes, copy number 6: AP000542.3, AP000542.1, AP000542.2.

Autosomal genes at a single copy (total copy number 1): 701. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
